Somatic mutation profile of tumor specimen MMRF_1955_1_BM_CD138pos (aliquot MMRF_1955_1_BM_CD138pos_T1_KBS5U_L06454) from MMRF case MMRF_1955, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.2 years (23,822 days).
Specimen MMRF_1955_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ea0f323-2f68-45e6-b969-eb50f1944890.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1955_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1955_1_PB_Whole_C2_KBS5U_L06487; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdf6d586-2264-475b-84e8-55262418e9a9

The open-access MAF lists 120 somatic variants for this specimen: 47 protein-altering or splice-affecting, 13 silent, 60 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, 3'UTR 33, Intron 17, Silent 13, 5'UTR 4, 3'Flank 4, Nonsense Mutation 3, 5'Flank 2, Frame Shift Ins 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 12/162 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 53/312 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRA3 | c.3275G>T p.S1092I | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as COSV51564573; called by muse, mutect2, varscan2
- AFAP1L2 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs749119012; called by muse, mutect2, varscan2
- ARHGAP44 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as rs1172492153; called by muse, mutect2, varscan2
- ATXN3L | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.716); catalogued as COSV101019332; called by muse, mutect2
- C19orf57 | c.1053G>C p.E351D | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as rs983428153; called by muse, mutect2
- CACNA1I | c.1432G>A p.G478R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1329856144; called by muse, mutect2
- CNTF | c.293T>G p.F98C | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV60160554; called by muse, mutect2, varscan2
- CNTF | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs575416876, COSV60161033, COSV60162162; called by muse, mutect2, varscan2
- DAW1 | c.814G>T p.D272Y | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59367760; called by muse, mutect2, varscan2
- DSCAM | c.3031C>T p.H1011Y | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as rs1328402038; called by muse, mutect2, varscan2
- GUCY1A2 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 81/218 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs763071550, COSV56489770; called by muse, mutect2, varscan2
- IGHV2-70D | c.158T>C p.M53T | Missense Mutation (SNP) | VAF 56/62 reads (90%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs1555598153; called by muse, mutect2, varscan2
- MSI2 | c.271-4C>T | Splice Region (SNP) | VAF 33/114 reads (29%) | catalogued as rs747256635, COSV52358432; called by muse, mutect2, varscan2
- NKAP | c.1116G>C p.Q372H | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57629856; called by muse, mutect2, varscan2
- OR13C3 | c.906del p.K302Nfs*5 | Frame Shift Del (DEL) | VAF 32/282 reads (11%) | catalogued as COSV66166327; called by mutect2, pindel
- PLCL1 | c.1685C>G p.A562G | Missense Mutation (SNP) | VAF 110/187 reads (59%) | SIFT tolerated (0.26); PolyPhen benign (0.055); catalogued as rs1443191984, COSV101406780; called by muse, mutect2, varscan2
- WDFY3 | c.2632G>A p.V878M | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.175); catalogued as COSV55705043, COSV55713711; called by muse, mutect2, varscan2
- ZNF534 | c.1003G>A p.G335R (on ENST00000332323 / NM_001143939.3; = p.G322R on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56522005; called by muse, mutect2, varscan2
- ARAP3 | c.1585G>A p.G529S | Missense Mutation (SNP) | VAF 11/296 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); called by muse, mutect2
- ASAP3 | c.897G>T p.K299N | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- C5 | c.1330G>T p.E444* | Nonsense Mutation (SNP) | VAF 30/278 reads (11%) | called by muse, mutect2, varscan2
- CDK5RAP2 | c.1525T>A p.Y509N | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CNOT2 | c.626C>G p.S209* | Nonsense Mutation (SNP) | VAF 6/137 reads (4%) | called by muse, mutect2
- CYP4F12 | c.772A>G p.R258G | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- DENND4C | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 104/329 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUOXA2 | c.15C>G p.N5K | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- FHAD1 | c.3622A>G p.R1208G | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- FOXO3 | c.1393T>C p.Y465H | Missense Mutation (SNP) | VAF 77/190 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- GRM8 | c.2675A>G p.N892S | Missense Mutation (SNP) | VAF 103/251 reads (41%) | SIFT tolerated (0.72); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IGSF1 | c.2344A>T p.K782* | Nonsense Mutation (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2
- KCNB1 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- MAX | c.107G>A p.R36K | Missense Mutation (SNP) | VAF 28/29 reads (97%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2T10 | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PARD3B | c.79A>G p.T27A | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PCARE | c.2420dup p.L808Sfs*3 | Frame Shift Ins (INS) | VAF 43/112 reads (38%) | called by mutect2, pindel, varscan2
- PRR32 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 62/125 reads (50%) | SIFT tolerated (0.9); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCAI | c.1232A>T p.K411M (on ENST00000336505 / NM_001144877.3; = p.K434M on NM_173690.5) | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TGFBRAP1 | c.385G>T p.V129L | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- TP53BP1 | c.4205G>A p.G1402D | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TSHZ3 | c.2921C>T p.P974L | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TUBGCP5 | c.19C>G p.P7A | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- WNT7B | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ZNF534 | c.1004G>A p.G335E (on ENST00000332323 / NM_001143939.3; = p.G322E on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF568 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF770 | c.1051T>G p.L351V | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- COL5A2 | c.3906C>T p.C1302= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as rs532409377; called by muse, mutect2, varscan2
- GULP1 | c.6C>T p.N2= | Silent (SNP) | VAF 116/251 reads (46%) | called by muse, mutect2, varscan2
- MARK2 | c.258G>A p.K86= | Silent (SNP) | VAF 38/67 reads (57%) | catalogued as COSV100157888; called by muse, mutect2, varscan2
- MID1IP1 | c.345C>T p.S115= | Silent (SNP) | VAF 14/148 reads (9%) | called by muse, mutect2
- NCOR1 | c.6387G>A p.R2129= | Silent (SNP) | VAF 5/76 reads (7%) | catalogued as rs1205643843; called by muse, mutect2
- PLCB4 | c.3525A>C p.V1175= (on ENST00000278655 / NM_182797.3; = p.M1188L on NM_000933.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 114/260 reads (44%) | called by muse, mutect2, varscan2
- PRSS27 | c.12G>A p.P4= | Silent (SNP) | VAF 54/98 reads (55%) | catalogued as rs1236989276; called by muse, mutect2, varscan2
- SEMA4G | c.1845C>T p.D615= (on ENST00000370250; = p.D620= on NM_017893.3) | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs142773171; called by muse, varscan2
- SIPA1L3 | c.3408C>T p.F1136= | Silent (SNP) | VAF 33/66 reads (50%) | called by muse, mutect2, varscan2
- SV2A | c.2004G>A p.A668= | Silent (SNP) | VAF 61/124 reads (49%) | catalogued as rs181498009; called by muse, mutect2, varscan2
- SYNJ2 | c.1050G>A p.E350= | Silent (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- TLR3 | c.1695C>T p.H565= | Silent (SNP) | VAF 71/152 reads (47%) | called by muse, mutect2, varscan2
- ZNF469 | c.7047G>A p.P2349= (on ENST00000437464; = p.P2377= on NM_001367624.2) | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as rs773655006, COSV71259144; called by mutect2, varscan2
- AC093512.2 | c.*621+22G>T | Intron (SNP) | VAF 48/96 reads (50%) | called by muse, mutect2, varscan2
- ACSM3 | c.1326+156A>C | Intron (SNP) | VAF 48/139 reads (35%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.*5813G>T | 3'UTR (SNP) | VAF 20/96 reads (21%) | called by muse, mutect2, varscan2
- AGMO | c.1263+7257A>T | Intron (SNP) | VAF 25/74 reads (34%) | called by muse, mutect2, varscan2
- ANO5 | c.-93A>T | 5'UTR (SNP) | VAF 16/141 reads (11%) | called by muse, mutect2, varscan2
- ARL6IP5 | c.394+52T>C | Intron (SNP) | VAF 19/28 reads (68%) | called by muse, mutect2, varscan2
- ASB4 | c.*883T>G | 3'UTR (SNP) | VAF 44/79 reads (56%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021133 del TGGTACTGAAGTCAGGAATGGCTT | 5'Flank (DEL) | VAF 36/112 reads (32%) | called by mutect2, pindel, varscan2
- BOD1L1 | c.243+1055G>A | Intron (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- C21orf91 | c.*4015_*4018del | 3'UTR (DEL) | VAF 32/100 reads (32%) | catalogued as rs1426749913; called by mutect2, pindel, varscan2
- CCDC180 | chr9:97307544 T>A | 5'Flank (SNP) | VAF 18/199 reads (9%) | called by muse, mutect2
- CDH19 | c.*2779T>C | 3'UTR (SNP) | VAF 15/59 reads (25%) | catalogued as rs1016615840; called by muse, mutect2, varscan2
- CHST11 | c.*252T>G | 3'UTR (SNP) | VAF 23/72 reads (32%) | called by muse, mutect2, varscan2
- CHST13 | c.*73C>A | 3'UTR (SNP) | VAF 45/99 reads (45%) | called by muse, mutect2, varscan2
- CLASP2 | c.716-536T>A | Intron (SNP) | VAF 33/390 reads (8%) | called by muse, mutect2
- CLCN5 | chrX:50094201 C>T | 3'Flank (SNP) | VAF 40/70 reads (57%) | catalogued as rs782036109, COSV56582702; called by muse, mutect2, varscan2
- CNTN4 | c.*1348T>G | 3'UTR (SNP) | VAF 13/94 reads (14%) | called by muse, mutect2, varscan2
- CPQ | c.*290C>T | 3'UTR (SNP) | VAF 53/118 reads (45%) | called by muse, mutect2, varscan2
- CUX1 | c.*4357C>T | 3'UTR (SNP) | VAF 48/97 reads (49%) | called by muse, mutect2, varscan2
- CYFIP2 | c.993-95T>A | Intron (SNP) | VAF 25/57 reads (44%) | called by muse, mutect2, varscan2
- DPM2 | c.196+313T>C | Intron (SNP) | VAF 10/101 reads (10%) | called by muse, mutect2, varscan2
- ETV1 | chr7:13894271 A>T | 3'Flank (SNP) | VAF 21/43 reads (49%) | called by muse, mutect2, varscan2
- FAM136A | c.87+229C>A | Intron (SNP) | VAF 9/81 reads (11%) | called by muse, mutect2
- FAM171A1 | c.*296G>T | 3'UTR (SNP) | VAF 26/125 reads (21%) | called by muse, mutect2, varscan2
- FBN2 | c.952+76T>G | Intron (SNP) | VAF 9/19 reads (47%) | called by muse, varscan2
- FIGN | c.*1070C>A | 3'UTR (SNP) | VAF 40/81 reads (49%) | called by muse, mutect2, varscan2
- GDA | c.*2574A>G | 3'UTR (SNP) | VAF 13/148 reads (9%) | called by muse, mutect2
- GNAL | chr18:11881524 G>A | 3'Flank (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- HNF4G | chr8:75566439 A>C | 3'Flank (SNP) | VAF 27/45 reads (60%) | called by muse, mutect2, varscan2
- KDM5A | c.*1315T>A | 3'UTR (SNP) | VAF 4/45 reads (9%) | catalogued as rs943164207, COSV66990396; called by muse, mutect2
- KLF13 | c.*1334A>G | 3'UTR (SNP) | VAF 30/86 reads (35%) | called by muse, mutect2, varscan2
- MBNL3 | c.*201A>C | 3'UTR (SNP) | VAF 48/102 reads (47%) | called by muse, mutect2, varscan2
- METTL23 | c.-34C>T | 5'UTR (SNP) | VAF 10/15 reads (67%) | catalogued as rs1483145817; called by muse, mutect2, varscan2
- NAV3 | c.-140C>A | 5'UTR (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- NRXN1 | c.*213A>T | 3'UTR (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- OGDHL | c.375+111C>T | Intron (SNP) | VAF 3/11 reads (27%) | catalogued as rs1167742031; called by muse, mutect2
- PCDH11X | c.*1966T>G | 3'UTR (SNP) | VAF 102/233 reads (44%) | called by muse, mutect2, varscan2
- PCMTD1 | c.*2373T>C | 3'UTR (SNP) | VAF 51/261 reads (20%) | called by muse, varscan2
- PCMTD1 | c.*2348G>T | 3'UTR (SNP) | VAF 40/183 reads (22%) | called by muse, varscan2
- PDE4D | c.456-59765T>C | Intron (SNP) | VAF 31/68 reads (46%) | called by muse, mutect2, varscan2
- PDPK1 | c.*1950A>C | 3'UTR (SNP) | VAF 18/164 reads (11%) | catalogued as rs568740588; called by muse, mutect2
- PHF14 | c.*751C>T | 3'UTR (SNP) | VAF 22/90 reads (24%) | called by muse, mutect2, varscan2
- PIK3R6 | c.189+69C>T | Intron (SNP) | VAF 23/177 reads (13%) | catalogued as rs1376931608; called by muse, mutect2, varscan2
- PLPPR5 | c.*2615T>A | 3'UTR (SNP) | VAF 30/79 reads (38%) | called by muse, mutect2, varscan2
- PPFIA2 | c.304-54454A>G | Intron (SNP) | VAF 26/68 reads (38%) | called by muse, mutect2, varscan2
- PTBP3 | c.*989G>A | 3'UTR (SNP) | VAF 52/131 reads (40%) | catalogued as rs1290673673; called by muse, mutect2, varscan2
- RGP1 | c.*1772G>T | 3'UTR (SNP) | VAF 52/166 reads (31%) | called by muse, mutect2, varscan2
- RPUSD4 | c.*1186T>C | 3'UTR (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2
- SERTAD2 | c.*1179T>A | 3'UTR (SNP) | VAF 24/72 reads (33%) | called by muse, mutect2, varscan2
- STEAP4 | c.*7324T>G | 3'UTR (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- SYTL4 | c.1005+386G>C | Intron (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2, varscan2
- TFAP2D | c.-81A>G | 5'UTR (SNP) | VAF 52/103 reads (50%) | called by muse, mutect2, varscan2
- TP53 | c.993+282T>G | Intron (SNP) | VAF 35/174 reads (20%) | called by muse, mutect2, varscan2
- UBE2R2 | c.*2527A>G | 3'UTR (SNP) | VAF 44/75 reads (59%) | called by muse, mutect2, varscan2
- VGLL4 | c.255-3807T>C | Intron (SNP) | VAF 11/133 reads (8%) | catalogued as rs1232622741; called by muse, mutect2
- VTI1A | c.*772C>T | 3'UTR (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- WWTR1 | c.*3211A>G | 3'UTR (SNP) | VAF 23/123 reads (19%) | called by muse, mutect2, varscan2
- XIAP | c.*5206A>C | 3'UTR (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2
- XIAP | c.*5208A>C | 3'UTR (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2
- ZMAT4 | c.*570G>A | 3'UTR (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
